Somatic mutation profile of tumor specimen ALCH-B4CB-TTP1-A (aliquot ALCH-B4CB-TTP1-A-1-0-D-A80E-36) from ALCHEMIST case ALCH-B4CB, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 76.8 years (28,065 days).
Specimen ALCH-B4CB-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f03719d9-4b06-43a2-884e-99d0413c570a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4CB-NB1-A (Blood Derived Normal), aliquot ALCH-B4CB-NB1-A-1-0-D-A80E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a6ec360b-84dc-4cb3-aa98-f989d38fbcf2

The open-access MAF lists 112 somatic variants for this specimen: 80 protein-altering or splice-affecting, 19 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 19, Intron 8, Frame Shift Del 3, Splice Site 2, RNA 2, 3'UTR 2, Frame Shift Ins 2, Nonsense Mutation 2, Translation Start Site 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALS2 | c.2911G>A p.V971M | Missense Mutation (SNP) | VAF 32/283 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as COSV99969326; called by muse, mutect2, varscan2
- APC2 | c.1886C>A p.T629K | Missense Mutation (SNP) | VAF 22/210 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs370595678; called by muse, mutect2, varscan2
- CCDC168 | c.6439A>G p.I2147V | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV70555051; called by muse, mutect2, varscan2
- COL5A3 | c.4134G>T p.M1378I | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV53408654; called by muse, mutect2, varscan2
- DCAF8L1 | c.235G>C p.V79L | Missense Mutation (SNP) | VAF 38/333 reads (11%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.038); catalogued as rs1196316727, COSV71595139; called by muse, mutect2, varscan2
- DDX43 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 37/411 reads (9%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs139171514; called by muse, mutect2
- EXT1 | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 39/401 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs377676265; called by muse, mutect2
- GRIN2C | c.3127C>T p.L1043F | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.157); catalogued as rs952364920; called by muse, mutect2, varscan2
- HIRIP3 | c.1601G>T p.R534L | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV104380089; called by muse, mutect2
- IL1R2 | c.770C>A p.P257Q | Missense Mutation (SNP) | VAF 19/191 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100208037; called by muse, mutect2
- KNDC1 | c.3454C>G p.L1152V | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs773972708; called by muse, mutect2, varscan2
- LIMD1 | c.1580A>T p.Y527F | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as rs200959391; called by muse, mutect2, varscan2
- MAP7D2 | c.1835A>T p.D612V | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.958); catalogued as COSV65529816; called by muse, mutect2, varscan2
- MPDZ | c.4383+1G>T p.X1461_splice | Splice Site (SNP) | VAF 18/124 reads (15%) | catalogued as rs1395982478; called by muse, mutect2
- NF1 | c.248A>C p.Q83P | Missense Mutation (SNP) | VAF 40/335 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.701); catalogued as CM1311450; called by muse, mutect2, varscan2
- NLRC3 | c.2462C>T p.A821V | Missense Mutation (SNP) | VAF 24/206 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.02); catalogued as rs1344546775; called by muse, mutect2, varscan2
- NTRK3 | c.175G>A p.G59R | Missense Mutation (SNP) | VAF 44/310 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.096); catalogued as COSV58133180; called by muse, mutect2, varscan2
- NXF3 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 34/296 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs764300277, COSV67702597; called by muse, mutect2, varscan2
- PHF21B | c.1440C>G p.D480E | Missense Mutation (SNP) | VAF 19/224 reads (8%) | SIFT tolerated (0.85); PolyPhen benign (0.007); catalogued as COSV100503429; called by muse, mutect2
- PIP5K1B | c.607G>T p.D203Y | Missense Mutation (SNP) | VAF 13/398 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55252766; called by muse, mutect2
- POF1B | c.865T>A p.F289I | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs1250282524; called by muse, mutect2, varscan2
- RP1 | c.5859G>T p.M1953I | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.084); catalogued as COSV55115012; called by muse, mutect2, varscan2
- SCUBE1 | c.2852C>A p.A951E | Missense Mutation (SNP) | VAF 31/212 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62609970; called by muse, mutect2, varscan2
- SERPINB4 | c.535G>C p.A179P | Missense Mutation (SNP) | VAF 30/358 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1395622867, COSV61985546; called by muse, mutect2
- SUSD4 | c.847G>A p.D283N | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758854269; called by muse, mutect2, varscan2
- TBC1D25 | c.1321C>A p.H441N | Missense Mutation (SNP) | VAF 34/262 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs868978113; called by muse, mutect2, varscan2
- TMBIM4 | c.317T>A p.L106Q | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1484934433, COSV53968907; called by muse, mutect2, varscan2
- TRPM5 | c.2350C>T p.R784W | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs146749699; called by muse, mutect2, varscan2
- UGGT1 | c.3002A>G p.Q1001R | Missense Mutation (SNP) | VAF 37/340 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs111733216; called by muse, mutect2, varscan2
- XK | c.337G>T p.G113C | Missense Mutation (SNP) | VAF 61/591 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66119873; called by muse, mutect2
- XKR7 | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1261310500, COSV101629320, COSV73813146; called by muse, mutect2
- ZNF407 | c.1520G>T p.R507L | Missense Mutation (SNP) | VAF 45/294 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV55247603; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3038T>A p.L1013Q | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2
- ADSS2 | c.258A>G p.I86M | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.759); called by muse, mutect2
- AKAP9 | c.8414A>T p.Q2805L (on ENST00000359028; = p.Q2781L on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/383 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- AXL | c.802G>T p.G268W | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CAPN7 | c.2350A>G p.I784V | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.007); called by muse, mutect2
- CATSPERB | c.3008T>C p.I1003T | Missense Mutation (SNP) | VAF 23/192 reads (12%) | SIFT tolerated (0.76); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- CCDC80 | c.749A>G p.Y250C | Missense Mutation (SNP) | VAF 33/293 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CEACAM5 | c.1958_1961del p.Y653Sfs*15 | Frame Shift Del (DEL) | VAF 42/320 reads (13%) | called by mutect2, pindel, varscan2
- COL20A1 | c.1629G>T p.E543D | Missense Mutation (SNP) | VAF 29/220 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- CPN1 | c.205C>G p.P69A | Missense Mutation (SNP) | VAF 24/248 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); called by muse, mutect2
- CREBBP | c.6145G>T p.A2049S | Missense Mutation (SNP) | VAF 37/235 reads (16%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- DCP2 | c.173C>A p.P58H | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- DNAH9 | c.8945A>T p.H2982L | Missense Mutation (SNP) | VAF 44/277 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- DTD2 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ELK1 | c.182G>T p.S61I | Missense Mutation (SNP) | VAF 32/251 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- F13A1 | c.2196G>T p.M732I | Missense Mutation (SNP) | VAF 74/524 reads (14%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FAM120C | c.2282C>T p.T761I | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); called by muse, mutect2
- FLG | c.1919C>A p.S640Y | Missense Mutation (SNP) | VAF 177/747 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GFRA4 | c.365A>G p.N122S | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- GRM8 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 6/70 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2
- HECW1 | c.3574C>A p.P1192T | Missense Mutation (SNP) | VAF 34/236 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- HSPG2 | c.11128C>T p.P3710S | Missense Mutation (SNP) | VAF 27/197 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- HTRA3 | c.916G>T p.G306W | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IFFO1 | c.608G>T p.R203L | Missense Mutation (SNP) | VAF 43/311 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ITGAD | c.2507C>A p.P836H | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- MBTPS2 | c.1431_1432insA p.A478Sfs*11 | Frame Shift Ins (INS) | VAF 49/460 reads (11%) | called by mutect2, varscan2
- MSR1 | c.218-1G>T p.X73_splice | Splice Site (SNP) | VAF 8/124 reads (6%) | called by muse, mutect2
- MSX1 | c.698C>A p.A233E | Missense Mutation (SNP) | VAF 33/259 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NAV3 | c.1154T>A p.L385H | Missense Mutation (SNP) | VAF 38/320 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR8A1 | c.845C>G p.P282R | Missense Mutation (SNP) | VAF 22/186 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PALLD | c.3216C>A p.D1072E (on ENST00000505667 / NM_001166108.2; = p.D1055E on NM_016081.4) | Missense Mutation (SNP) | VAF 50/486 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- PCDHB7 | c.445G>T p.G149W | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PEG3 | c.3400C>A p.L1134M | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- PHKA2 | c.979G>T p.E327* | Nonsense Mutation (SNP) | VAF 46/348 reads (13%) | called by muse, mutect2, varscan2
- PKN3 | c.1734C>A p.F578L | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.138); called by muse, mutect2
- PLOD2 | c.92C>A p.P31H | Missense Mutation (SNP) | VAF 37/297 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- SFTPB | c.890_891del p.S297* | Frame Shift Del (DEL) | VAF 70/560 reads (13%) | called by pindel, varscan2
- SIGLEC1 | c.5017C>T p.Q1673* | Nonsense Mutation (SNP) | VAF 29/224 reads (13%) | called by muse, mutect2, varscan2
- SLC16A11 | c.168dup p.R57Afs*9 (on ENST00000308009; = p.R33Afs*9 on NM_153357.3) | Frame Shift Ins (INS) | VAF 39/224 reads (17%) | called by mutect2, pindel, varscan2
- SYN3 | c.676G>T p.V226L | Missense Mutation (SNP) | VAF 26/245 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- SYT12 | c.443G>C p.G148A | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- THBS4 | c.715G>T p.D239Y | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TNR | c.260C>G p.A87G | Missense Mutation (SNP) | VAF 55/261 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- TRIM35 | c.986A>G p.Y329C | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- USP53 | c.1470_1471del p.G491Ifs*9 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | called by mutect2, pindel, varscan2
- VAV1 | c.2217G>T p.T739= | Splice Region (SNP) | VAF 7/127 reads (6%) | called by muse, mutect2
- XK | c.338G>T p.G113V | Missense Mutation (SNP) | VAF 60/590 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF257 | c.20G>T p.R7M | Missense Mutation (SNP) | VAF 25/185 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- AIRE | c.531C>A p.L177= | Silent (SNP) | VAF 30/267 reads (11%) | catalogued as COSV99381041; called by muse, varscan2
- ANKH | c.192T>A p.G64= | Silent (SNP) | VAF 71/762 reads (9%) | called by muse, mutect2
- CALHM2 | c.154C>A p.R52= | Silent (SNP) | VAF 43/349 reads (12%) | called by muse, mutect2, varscan2
- FSHR | c.1752C>T p.C584= | Silent (SNP) | VAF 11/178 reads (6%) | catalogued as rs768038206; called by muse, mutect2
- GPC4 | c.426C>T p.L142= | Silent (SNP) | VAF 20/234 reads (9%) | called by muse, mutect2
- IGSF10 | c.2316A>G p.R772= | Silent (SNP) | VAF 48/315 reads (15%) | called by muse, mutect2, varscan2
- MAGEB5 | c.270G>A p.E90= | Silent (SNP) | VAF 21/178 reads (12%) | called by muse, mutect2, varscan2
- MSL1 | c.102C>A p.P34= | Silent (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2, varscan2
- NCBP3 | c.189G>T p.T63= | Silent (SNP) | VAF 34/283 reads (12%) | called by muse, mutect2, varscan2
- OSCAR | c.684C>G p.A228= | Silent (SNP) | VAF 8/99 reads (8%) | called by muse, mutect2
- PAG1 | c.516A>G p.Q172= | Silent (SNP) | VAF 22/178 reads (12%) | called by muse, mutect2, varscan2
- PCM1 | c.150A>G p.K50= | Silent (SNP) | VAF 26/184 reads (14%) | called by muse, mutect2, varscan2
- PDE10A | c.852A>T p.I284= | Silent (SNP) | VAF 17/157 reads (11%) | called by muse, mutect2, varscan2
- PIGS | c.1332C>G p.S444= | Silent (SNP) | VAF 24/119 reads (20%) | called by muse, mutect2
- SALL3 | c.735G>A p.A245= | Silent (SNP) | VAF 9/105 reads (9%) | called by muse, mutect2
- SIM1 | c.1299G>T p.S433= | Silent (SNP) | VAF 20/169 reads (12%) | called by muse, mutect2, varscan2
- SLC41A3 | c.768G>T p.L256= | Silent (SNP) | VAF 34/412 reads (8%) | called by muse, mutect2
- SPDYE4 | c.246G>T p.V82= | Silent (SNP) | VAF 34/314 reads (11%) | catalogued as rs758557045, COSV60906339; called by muse, mutect2, varscan2
- ZNF157 | c.1479A>T p.I493= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV65659903; called by muse, mutect2, varscan2
- AIFM1 | c.1573+19T>A | Intron (SNP) | VAF 20/220 reads (9%) | called by muse, mutect2
- CETP | c.*51G>A | 3'UTR (SNP) | VAF 38/299 reads (13%) | called by muse, mutect2, varscan2
- DNAJC24 | c.111+3290A>T | Intron (SNP) | VAF 8/175 reads (5%) | called by muse, mutect2
- HERC2P2 | n.2226A>G | RNA (SNP) | VAF 73/706 reads (10%) | called by muse, mutect2, varscan2
- METTL24 | c.787-7654T>A | Intron (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
- NLRP12 | c.2244-179A>T | Intron (SNP) | VAF 11/72 reads (15%) | called by muse, mutect2, varscan2
- PALM2AKAP2 | c.582+32743G>T | Intron (SNP) | VAF 28/197 reads (14%) | called by muse, mutect2, varscan2
- RNF212 | c.247-2837G>C | Intron (SNP) | VAF 14/96 reads (15%) | called by muse, mutect2, varscan2
- RUFY4 | c.600+51C>A | Intron (SNP) | VAF 23/140 reads (16%) | called by muse, mutect2, varscan2
- SYP | c.102+24G>T | Intron (SNP) | VAF 29/278 reads (10%) | called by muse, mutect2, varscan2
- Z97192.4 | chr22:49657413 A>T | 3'Flank (SNP) | VAF 12/150 reads (8%) | called by muse, mutect2
- ZNF626 | c.*64A>G | 3'UTR (SNP) | VAF 28/213 reads (13%) | called by muse, mutect2, varscan2
- ZNF849P | n.599C>A | RNA (SNP) | VAF 41/369 reads (11%) | called by muse, mutect2, varscan2
